Somatic mutation profile of tumor specimen C3L-03392-01 (aliquot CPT0219080007) from CPTAC case C3L-03392, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.7 years (18,509 days).
Specimen C3L-03392-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e31b6355-6ff9-4b2d-b774-e43987544291.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03392-31 (Blood Derived Normal), aliquot CPT0220450002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d80da50-f1ed-4ecd-8dbe-81f57b57ef52

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, Intron 2, Nonsense Mutation 1, In Frame Del 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.3739_3742del p.F1247Ifs*18 | Frame Shift Del (DEL) | VAF 79/316 reads (25%) | catalogued as rs1064794276; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AFAP1L2 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 81/457 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs778065011, COSV100412127; called by muse, mutect2, varscan2
- AFM | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752418770, COSV56919799; called by muse, mutect2, varscan2
- CARD11 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.728); catalogued as COSV62717090, COSV62719204; called by muse, varscan2
- DHX9 | c.3496C>T p.R1166* | Nonsense Mutation (SNP) | VAF 26/188 reads (14%) | catalogued as COSV62358354; called by muse, mutect2
- GDF5 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 72/544 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs139413270; called by muse, mutect2, varscan2
- KCNK10 | c.1514C>T p.T505M | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.474); catalogued as rs201727669, COSV56649313; called by muse, mutect2, varscan2
- LOXL4 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766992310, COSV53256517; called by muse, mutect2, varscan2
- LPA | c.2533A>G p.R845G | Missense Mutation (SNP) | VAF 59/479 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.036); catalogued as rs747391174, COSV100307611; called by muse, mutect2, varscan2
- MAGEL2 | c.1805C>T p.T602M | Missense Mutation (SNP) | VAF 46/336 reads (14%) | SIFT tolerated, low confidence (0.28); catalogued as rs761204158, COSV100046175; called by muse, mutect2, varscan2
- NDRG1 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 77/630 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs780954647; called by muse, mutect2, varscan2
- OTOF | c.5027G>A p.R1676H (on ENST00000272371 / NM_194248.3; = p.R909H on NM_004802.4) | Missense Mutation (SNP) | VAF 50/338 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as rs143889717; called by muse, mutect2, varscan2
- PTPRN | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as rs149510025; called by muse, mutect2, varscan2
- SIGLEC9 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.062); catalogued as rs267605604, COSV51585994; called by muse, mutect2
- SLC36A4 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 15/211 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185165394, COSV58396955; called by muse, mutect2
- USP47 | c.1286_1288del p.P429del (on ENST00000399455 / NM_001372095.1; = p.P341del on NM_017944.4 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 18/80 reads (23%) | catalogued as rs768629120; called by pindel, varscan2
- XXYLT1 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.565); catalogued as rs1221377971; called by muse, mutect2, varscan2
- ZNF516 | c.2918C>T p.S973F | Missense Mutation (SNP) | VAF 52/335 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.726); catalogued as rs772404786; called by muse, mutect2, varscan2
- CLSTN3 | c.2398G>T p.V800F | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- MMP12 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTBP | c.1838A>G p.D613G | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- TFR2 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 76/758 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- TRIM4 | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR61 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- CRYBB3 | c.225C>T p.R75= | Silent (SNP) | VAF 48/263 reads (18%) | catalogued as rs761680838; called by muse, mutect2, varscan2
- CSF2RA | c.504C>T p.Y168= | Silent (SNP) | VAF 27/226 reads (12%) | catalogued as COSV62624150; called by muse, mutect2, varscan2
- EGFL7 | c.447C>G p.P149= | Silent (SNP) | VAF 35/272 reads (13%) | catalogued as rs1321022989; called by muse, mutect2, varscan2
- FSCN1 | c.966C>T p.G322= | Silent (SNP) | VAF 46/314 reads (15%) | catalogued as rs778208354; called by muse, mutect2, varscan2
- PAX6 | c.450C>T p.N150= | Silent (SNP) | VAF 78/651 reads (12%) | catalogued as rs780920168, CD982860, COSV53795006; called by muse, mutect2, varscan2
- PRAMEF7 | c.1293A>G p.E431= | Silent (SNP) | VAF 77/1199 reads (6%) | called by muse, mutect2
- TNFRSF8 | c.1032G>A p.A344= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs374404049; called by muse, mutect2, varscan2
- DIAPH3 | c.2737+53A>G | Intron (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- LUC7L | c.61+300C>T | Intron (SNP) | VAF 11/76 reads (14%) | catalogued as rs750673454; called by muse, mutect2, varscan2
- RNA5-8SP2 | n.128C>T | RNA (SNP) | VAF 13/79 reads (16%) | catalogued as rs1203667609; called by muse, mutect2, varscan2
